Somatic mutation profile of tumor specimen TCGA-ZH-A8Y3-01A (aliquot TCGA-ZH-A8Y3-01A-11D-A46P-09) from TCGA case TCGA-ZH-A8Y3, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.4 years (22,436 days).
Specimen TCGA-ZH-A8Y3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4027a755-e540-4790-8768-a58ddabbe2ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y3-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y3-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9020f8f-05eb-4247-9d4b-bc7232690e53

The open-access MAF lists 38 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 27, Silent 5, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- DCAF4L2 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV60476978, COSV60484022; called by muse, mutect2, varscan2
- FAM50A | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV50132200; called by muse, mutect2, varscan2
- GNPTAB | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs745438711; called by muse, mutect2, varscan2
- GPR61 | c.817del p.Q273Rfs*40 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs1171793286; called by pindel, varscan2
- PHF20L1 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as rs1459722057; called by muse, mutect2
- SDK2 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs769841452; called by muse, mutect2, varscan2
- TRIM54 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV56085865; called by muse, mutect2, varscan2
- VPS25 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768858788; called by muse, mutect2, varscan2
- ZNF354B | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as rs1459258230; called by muse, mutect2
- AIRE | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AREG | c.339C>A p.N113K | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- CBLL1 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC105 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD244 | c.1055C>T p.A352V (on ENST00000368033 / NM_001166663.2; = p.A347V on NM_016382.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CECR2 | c.2443G>A p.G815R (on ENST00000342247 / NM_001290047.2; = p.G632R on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHM | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNDP1 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DUSP18 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GUCA1B | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MC4R | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MIDEAS | c.932T>C p.F311S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MITF | c.613G>T p.E205* (on ENST00000448226 / NM_006722.3; = p.E99* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- MTMR12 | c.1521A>C p.E507D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NEB | c.9994C>A p.P3332T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PBRM1 | c.3162_3179del p.D1055_E1060del (on ENST00000296302 / NM_001366071.2; = p.D1030_E1035del on NM_018313.5) | In Frame Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- PCDH15 | c.2585A>T p.K862M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PHLDB2 | c.3625C>T p.P1209S (on ENST00000393925 / NM_001134439.2; = p.P1166S on NM_145753.2) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- PPP1R18 | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC22A23 | c.1724T>A p.V575E | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYTL4 | c.1559-1G>A p.X520_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- TCIRG1 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- WNK1 | c.2293_2294insGGAT p.S765Wfs*4 (on ENST00000315939 / NM_018979.4; = p.S764Wfs*4 on NM_014823.3) | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- CADM1 | c.681C>T p.V227= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100523417; called by muse, mutect2, varscan2
- CARD6 | c.465T>C p.Y155= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- H2BC5 | c.357C>T p.V119= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs778587163; called by muse, mutect2, varscan2
- PEAK3 | c.39C>T p.P13= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs764995528, COSV100574358, COSV59700879; called by muse, mutect2, varscan2
- WDTC1 | c.213G>T p.T71= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV60089534; called by muse, varscan2
